Gene-level copy-number profile of tumor specimen TCGA-CD-8525-01A from TCGA case TCGA-CD-8525, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 82.1 years (30,004 days).
Specimen TCGA-CD-8525-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.948dc3b8-f4e7-4502-9c2a-abc950959270.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CD-8525-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/725035aa-e60a-4d1f-a68f-04a46c8b2df4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 746; copy number 2: 17,640; copy number 3: 11,736; copy number 4: 19,019; copy number 5: 6,893; copy number 6: 2,328; copy number 7: 1,050; copy number 8: 97; copy number 9: 105; copy number 10: 90; copy number 11: 27; copy number 13: 42; copy number 14: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CD-8525-01A-11D-2338-01): tumor purity 0.3, ploidy 3.09, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–454,070, 19 genes (within-gene range 0–2): BNIP3P41, ZNF595, AC253576.1, ZNF718, AC253576.2, AC108475.1, ZNF876P, AC079140.3, AC079140.5, ZNF732, AC079140.6, AC079140.4, ZNF141, AC079140.1, AC079140.2, MIR571, AC092574.2, ZNF519P4, AC092574.1.
- chr9:9,090,898–9,803,784, 3 genes: RPS26P3, RN7SL5P, AL513422.1.
- chr16:78,793,584–78,899,644, 5 genes: AC009141.1, RPS3P7, AC136603.1, AC027279.4, AC027279.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10,645 genes in 48 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:147,713,455–180,007,297, 475 genes, copy number 5 (broad region; genes not listed).
- chr3:42,321,005–43,055,871, 32 genes, copy number 6 (within-gene range 4–6): SALL4P6, EIF4BP4, LYZL4, RPL35AP8, VIPR1, VIPR1-AS1, SEC22C, SS18L2, NKTR, AC006059.1, ZBTB47, AC006059.5, RN7SL567P, KLHL40, HHATL, AC006059.3, HHATL-AS1, CCDC13, AC006059.2, AC006059.4, CCDC13-AS1, LINC02158, HIGD1A, AC099329.1, ACKR2, AC099329.2, AC092042.3, KRBOX1, CYP8B1, HNRNPA1P22, ZNF662, KRBOX1-AS1.
- chr3:147,386,046–174,378,005, 412 genes, copy number 5–7 (broad region; genes not listed).
- chr4:123,490,242–124,062,990, 8 genes, copy number 7: AC093821.1, LINC02435, LINC01091, AC096732.1, RPL21P50, AC093767.1, AC108075.1, PPIAP76.
- chr4:184,254,509–184,490,293, 10 genes, copy number 6: AC079080.1, RN7SL28P, MYL12BP2, LINC02363, LINC02362, IRF2, SNORD79, AC099343.2, IRF2-DT, AC099343.3.
- chr5:58,198–45,895,970, 710 genes, copy number 5–7 (broad region; genes not listed).
- chr6:17,224,243–21,602,383, 60 genes, copy number 6–8: AL136305.1, RBM24, AL034372.1, CAP2, RPL7P26, SUMO2P13, AL138824.1, FAM8A1, NUP153, RNU6-190P, AL138724.1, RNA5SP204, Y_RNA, KIF13A, AL023807.1, NHLRC1, TPMT, KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1, AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3.
- chr6:39,553,811–42,722,597, 77 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:2,033,508–6,036,974, 35 genes, copy number 5: AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1, AC115485.1, AC023296.1, CSMD1, AC026991.1, AC026991.2, RNA5SP251, AC027251.1, AC010941.1, AC022068.1, PAICSP4, AC019176.1, AC019176.2, SNORA70, RN7SL318P, AC007718.1, AC091193.1, RPL23AP54, AC004944.1, AC084768.1, AC084768.2, AC087369.1, AC087369.2, RN7SKP159, AC079054.1.
- chr8:47,667,771–143,023,832, 1,365 genes, copy number 6–7 (broad region; genes not listed).
- chr9:133,061,978–133,406,096, 23 genes, copy number 5 (within-gene range 3–5): CEL, CELP, RALGDS, AL162417.1, GBGT1, OBP2B, LCN1P1, ABO, Y_RNA, LCN1P2, SURF6, Y_RNA, MED22, AL772161.1, RPL7A, SNORD24, SNORD36B, SNORD36A, SNORD36C, SURF1, SURF2, SURF4, STKLD1.
- chr10:3,200,829–5,945,900, 68 genes, copy number 7–10 (broad region; genes not listed).
- chr10:10,776,223–12,043,170, 19 genes, copy number 6 (within-gene range 2–6): AL136452.1, SFTA1P, CELF2, LINC00710, AL136369.2, AL136369.1, AL162408.1, CELF2-AS2, AL136320.1, CELF2-AS1, AC026887.1, USP6NL, AL512631.2, AL512631.1, ECHDC3, PROSER2, PROSER2-AS1, UPF2, RNU6-1095P.
- chr10:24,583,609–25,176,276, 12 genes, copy number 7: ARHGAP21, RNA5SP305, AL157385.2, PRTFDC1, AL157385.1, RN7SKP241, AL512598.2, AL512598.1, ENKUR, THNSL1, LINC01516, GPR158-AS1.
- chr10:26,216,665–27,288,824, 27 genes, copy number 11 (within-gene range 2–11): GAD2, AL355798.1, APBB1IP, RNA5SP307, AL160287.1, FAM238A, AL390961.1, FAM238B, SELENOOLP, AL390961.3, PDSS1, HSPA8P3, AL390961.2, ABI1, AL139404.1, RNU6-946P, FAM238C, ANKRD26, RNU6-490P, YME1L1, MASTL, ACBD5, RNU2-24P, RNU7-12P, AL160291.1, LRRC37A6P, ARMC4P1.
- chr10:29,891,032–30,591,092, 21 genes, copy number 8: AL353093.1, JCAD, RNU6-598P, EEF1A1P39, AL353796.1, MTPAP, AL353796.2, DNM1P17, GOLGA2P6, RN7SL241P, MIR7162, NIFKP1, AL161651.1, CCND3P1, MAP3K8, HNRNPA1P32, AL590068.4, AL590068.1, RN7SL63P, AL590068.2, AL590068.3.
- chr10:36,940,109–38,080,877, 29 genes, copy number 8: AL390061.1, MKNK2P1, ARL6IP1P2, ANKRD30A, RNU6-811P, AL157387.1, LINC00993, RN7SL314P, Y_RNA, TMEM161BP1, VN1R53P, TACC1P1, MTND1P18, MTRNR2L7, AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3.
- chr10:51,319,826–52,772,784, 8 genes, copy number 5: RSU1P3, CSTF2T, PRKG1-AS1, DKK1, RPL31P44, THAP12P3, LNCAROD, MBL2.
- chr10:57,304,479–57,982,993, 4 genes, copy number 13: MIR3924, AL731534.1, AC006484.1, MRPS35P3.
- chr10:58,999,482–59,960,913, 13 genes, copy number 14 (within-gene range 2–14): LINC00844, RPLP1P10, TRAF6P1, PHYHIPL, FAM13C, AC025038.1, AL355474.1, MRPL50P4, AC026391.1, SLC16A9, MRLN, CCDC6, LINC01553.
- chr10:60,684,505–61,001,440, 5 genes, copy number 9: ARL4AP1, ANK3-DT, CDK1, RHOBTB1, RNU2-72P.
- chr10:61,406,642–64,693,446, 37 genes, copy number 13 (within-gene range 2–13): TMEM26, TMEM26-AS1, AL356952.1, CABCOCO1, AL451049.1, LINC02625, ARID5B, RTKN2, LINC02621, AC024597.1, RN7SL591P, ZNF365, AC024598.1, AC067752.1, AC067751.1, ALDH7A1P4, ADO, EGR2, RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3, AC022387.2, MRPL35P2, AC022387.1, AC013287.1, RPL7AP50, AC012558.1, DBF4P1, RPL17P35.
- chr10:66,837,457–68,075,301, 19 genes, copy number 8: AL607023.1, LRRTM3, AL139240.1, RPL7AP51, MIR7151, AKR1B10P1, RPL21P92, DNAJC12, RNU6-1250P, RN7SL394P, DNAJC19P1, AL133551.1, RNU6-523P, RPL12P8, SIRT1, HERC4, RPS3AP38, RN7SL220P, POU5F1P5.
- chr10:71,790,747–75,182,123, 115 genes, copy number 7–10 (broad region; genes not listed).
- chr10:84,328,586–86,366,795, 21 genes, copy number 5 (within-gene range 2–5): CCSER2, RPL12P29, TNPO1P1, CACYBPP1, RPS3AP5, AL358787.2, LINC01519, AL358787.1, LINC02647, AC025428.1, LINC01520, AL731532.1, RNU6-325P, AL731532.2, GRID1-AS1, GRID1, AC022028.3, AC022028.2, RN7SKP238, AC022028.1, RNA5SP322.
- chr10:97,498,924–133,761,125, 635 genes, copy number 6 (broad region; genes not listed).
- chr11:18,000,542–26,723,427, 130 genes, copy number 5 (broad region; genes not listed).
- chr11:27,888,838–135,075,908, 2,588 genes, copy number 5 (broad region; genes not listed).
- chr12:30,086,342–31,993,107, 60 genes, copy number 5: AC023511.3, AC023511.2, AC023511.1, LINC02386, AC078776.2, RNA5SP356, AC078776.1, AC026371.1, IPO8, AC012673.1, CAPRIN2, AC010198.1, LINC00941, AC010198.2, PPIAP44, TSPAN11, AC008013.1, AC008013.2, DDX11-AS1, DDX11, SNORA75, AC008013.3, AC024940.1, AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1.
- chr12:45,444,766–46,876,784, 22 genes, copy number 5: AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4.
- chr12:99,647,753–102,481,744, 65 genes, copy number 5 (broad region; genes not listed).
- chr13:18,467,172–84,902,424, 988 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr15:66,808,404–101,933,350, 907 genes, copy number 5 (broad region; genes not listed).
- chr16:8,780,384–9,518,325, 19 genes, copy number 5: TMEM186, PMM2, AC012173.1, AC022167.2, CARHSP1, AC022167.1, AC022167.4, LITAFD, USP7, AC022167.3, AC087190.2, C16orf72, AC087190.3, AC087190.1, RPL21P119, LINC02177, AC012178.1, LINC01177, LINC01195.
- chr18:9,136,228–9,960,021, 28 genes, copy number 5 (within-gene range 2–5): ANKRD12, Y_RNA, Y_RNA, AP001033.2, AP001033.1, TWSG1, AP001033.3, AP005432.2, RALBP1, AP005432.1, RNU2-27P, PPP4R1, AP001381.1, PPP4R1-AS1, RNU6-903P, LINC02856, KRT18P8, RAB31, AP000902.1, ZNF415P1, RN7SL862P, AC006238.2, RNA5SP449, PIGPP4, TXNDC2, AC006238.1, VAPA, RNA5SP450.
- chr19:22,391,019–32,072,113, 165 genes, copy number 7–9 (within-gene range 2–9) (broad region; genes not listed).
- chr19:32,405,543–33,927,625, 45 genes, copy number 9: DPY19L3, PDCD5, ANKRD27, SNORA68B, RPS12P31, RN7SL789P, AC008474.1, RGS9BP, AC008736.1, NUDT19, AC008736.2, TDRD12, AC008805.1, SLC7A9, AC008805.2, RN7SKP22, CEP89, RPL31P60, FAAP24, RHPN2, AC008521.1, AC008521.2, GPATCH1, WDR88, LRP3, AC008738.1, AC008738.7, SLC7A10, AC008738.4, AC008738.6, AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2, RPS3AP50, AKR1B1P7, CEBPG, PEPD, AC010485.1, RPL21P131, CHST8, KCTD15, AC008556.1, RN7SL150P.
- chr20:19,693,209–64,313,132, 1,083 genes, copy number 5–7 (broad region; genes not listed).
- chr22:36,991,120–37,427,479, 20 genes, copy number 7 (within-gene range 3–7): TEX33, TST, Y_RNA, MPST, Z73420.1, KCTD17, RN7SKP214, TMPRSS6, AL022314.1, IL2RB, Z82188.2, C1QTNF6, SSTR3, Z82188.1, RAC2, CYTH4, ELFN2, Z94160.1, ELFN2, Z94160.2.
- chr22:41,301,525–50,801,309, 276 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 746. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
